Somatic mutation profile of tumor specimen 0DTREG from CCDI case PBCICU, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Atypical teratoid/rhabdoid tumor; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.7 years (978 days).
Specimen 0DTREG: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ee8d9325-887c-4030-bec4-4f8615b917c4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTREN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7eac399a-8e7b-4f02-aea2-d258aa347bda

The open-access MAF lists 26 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Intron 3, 3'UTR 2, 5'UTR 1, Nonsense Mutation 1, Splice Site 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CHRNB4 | c.689G>A p.R230H | Missense Mutation (SNP) | VAF 114/303 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770629950, COSV55717908; called by muse, mutect2, varscan2
- HSD17B10 | c.360G>A p.V120= | Splice Region (SNP) | VAF 91/297 reads (31%) | catalogued as rs370477229; called by muse, mutect2, varscan2
- KCNH8 | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 46/1675 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1292204185; called by muse, mutect2
- LVRN | c.938G>A p.C313Y | Missense Mutation (SNP) | VAF 296/1253 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100773678; called by muse, mutect2, varscan2
- OSGEPL1 | c.575C>G p.S192C | Missense Mutation (SNP) | VAF 31/1240 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1472939869; called by muse, mutect2
- PSD2 | c.1021G>A p.E341K | Missense Mutation (SNP) | VAF 139/403 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs768303780, COSV51200599; called by muse, mutect2, varscan2
- PSG9 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 138/398 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0.331); catalogued as rs754439413; called by muse, mutect2, varscan2
- SLC35B4 | c.433C>A p.Q145K | Missense Mutation (SNP) | VAF 30/835 reads (4%) | SIFT tolerated (0.96); PolyPhen benign (0.021); catalogued as COSV101043110; called by muse, mutect2
- COL4A2 | c.3123_3139dup p.L1047Sfs*26 | Frame Shift Ins (INS) | VAF 116/326 reads (36%) | called by mutect2, varscan2
- EHBP1 | c.3673G>C p.E1225Q | Missense Mutation (SNP) | VAF 517/1283 reads (40%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- IQCM | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 134/714 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC63 | c.764-1G>T p.X255_splice | Splice Site (SNP) | VAF 206/629 reads (33%) | called by muse, mutect2, varscan2
- PIK3CG | c.82G>T p.A28S | Missense Mutation (SNP) | VAF 40/1012 reads (4%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0); called by muse, mutect2
- RYR2 | c.13358C>A p.A4453D | Missense Mutation (SNP) | VAF 131/1217 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- TIGD3 | c.1336G>T p.E446* | Nonsense Mutation (SNP) | VAF 198/514 reads (39%) | called by muse, mutect2, varscan2
- ANK2 | c.6396C>A p.T2132= | Silent (SNP) | VAF 417/1174 reads (36%) | called by muse, mutect2, varscan2
- BAD | c.420G>A p.Q140= | Silent (SNP) | VAF 273/687 reads (40%) | catalogued as rs368322510; called by muse, mutect2, varscan2
- NRN1L | c.240C>T p.A80= | Silent (SNP) | VAF 188/492 reads (38%) | called by muse, mutect2, varscan2
- PKHD1L1 | c.2394C>T p.L798= | Silent (SNP) | VAF 312/912 reads (34%) | catalogued as rs11987091; called by muse, varscan2
- TEC | c.1440G>T p.L480= | Silent (SNP) | VAF 32/802 reads (4%) | called by muse, mutect2
- C3orf70 | c.*61G>A | 3'UTR (SNP) | VAF 30/382 reads (8%) | catalogued as rs889446152; called by muse, mutect2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 24/219 reads (11%) | called by muse, varscan2
- MAP1LC3A | c.*20G>A | 3'UTR (SNP) | VAF 49/273 reads (18%) | catalogued as COSV54164311; called by muse, mutect2, varscan2
- NEK11 | c.1083-35G>A | Intron (SNP) | VAF 117/332 reads (35%) | catalogued as rs527343087, COSV63584543; called by muse, mutect2, varscan2
- PKP1 | c.-71G>A | 5'UTR (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- PTPRN | c.1603+16A>G | Intron (SNP) | VAF 174/380 reads (46%) | catalogued as rs1171023879; called by muse, mutect2, varscan2
